Somatic mutation profile of tumor specimen MMRF_2144_1_BM_CD138pos (aliquot MMRF_2144_1_BM_CD138pos_T1_KHS5U_L08701) from MMRF case MMRF_2144, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.0 years (26,301 days).
Specimen MMRF_2144_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b88a65fb-8d08-4a33-9cdb-b9b945208781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2144_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2144_1_PB_Whole_C2_KHS5U_L08700; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/932cf9b7-3f91-442a-b197-ebf413863823

The open-access MAF lists 114 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 24, Intron 19, Silent 11, 5'UTR 6, Splice Region 4, Frame Shift Del 3, RNA 3, 3'Flank 2, Translation Start Site 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASP8 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966418; called by muse, mutect2
- FGF19 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99594422; called by muse, mutect2, varscan2
- IRF8 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1408985036; called by muse, mutect2, varscan2
- LAMB3 | c.3026G>A p.R1009Q | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs753174535; called by muse, mutect2, varscan2
- MED23 | c.3928G>A p.V1310M | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs756261655; called by muse, mutect2, varscan2
- MMP3 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs782754459, COSV55406336; called by muse, mutect2, varscan2
- PABPC4L | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1201151048; called by muse, mutect2, varscan2
- PLCZ1 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs764883389, COSV56858403; called by muse, mutect2, varscan2
- RYR2 | c.4489G>A p.G1497R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs748678280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM4 | c.3632G>A p.R1211H | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as rs555336301, COSV99578977; called by muse, mutect2, varscan2
- ACAN | c.4460T>A p.I1487N | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ADAMTS20 | c.2501A>T p.H834L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKR1E2 | c.342G>C p.W114C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- BHLHE41 | c.1271_1289del p.E424Afs*73 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, varscan2
- CCDC191 | c.1467T>A p.C489* | Nonsense Mutation (SNP) | VAF 183/390 reads (47%) | called by muse, mutect2, varscan2
- COL12A1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- DUSP2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EGR1 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- EHD3 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- EPHA7 | c.673T>G p.S225A | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAM135B | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FOXN1 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.013); called by muse, mutect2
- GGA3 | c.126-2A>G p.X42_splice | Splice Site (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2
- GJA10 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GPX6 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.3254A>G p.Y1085C | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2
- IGLV3-1 | c.165_214delinsACAAAAGCCAGGCCAGTCCCCTGTATTGGTCATCTATCAAGATGACAGGA p.S70_K71delinsDR | Missense Mutation (ONP) | VAF 9/60 reads (15%) | called by muse*, pindel
- LAMP5 | c.780C>G p.H260Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- MAX | c.113A>C p.H38P | Missense Mutation (SNP) | VAF 30/30 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBOAT2 | c.81C>A p.N27K | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MRPS7 | c.507+5A>G | Splice Region (SNP) | VAF 58/104 reads (56%) | called by muse, mutect2, varscan2
- NEBL | c.2346G>T p.M782I | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NEU2 | c.1127A>T p.E376V | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHP1 | c.1881+8G>T | Splice Region (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- NR2C1 | c.966-4A>G | Splice Region (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- PNOC | c.208_237del p.W70_H79del | In Frame Del (DEL) | VAF 28/276 reads (10%) | called by mutect2, pindel
- RGL1 | c.1035del p.T346Lfs*11 (on ENST00000360851 / NM_001297672.2; = p.T381Lfs*11 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 52/117 reads (44%) | called by mutect2, pindel, varscan2
- RYR2 | c.6125A>C p.K2042T | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- S100A7A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC45A4 | c.1313A>T p.Y438F (on ENST00000517878 / NM_001286646.2; = p.Y387F on NM_001080431.2) | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2
- SPARCL1 | c.70T>A p.L24I | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- STARD5 | c.494+7A>G | Splice Region (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- STRN | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE1 | c.20244A>C p.Q6748H (on ENST00000367255 / NM_182961.4; = p.Q6677H on NM_033071.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TLX3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRAF3 | c.115del p.Y39Tfs*6 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- WDR48 | c.1927T>A p.C643S | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR1 | c.1395C>A p.T465= | Silent (SNP) | VAF 90/204 reads (44%) | called by muse, mutect2, varscan2
- CHRND | c.1074C>T p.L358= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- MPDZ | c.2820T>C p.I940= | Silent (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- NFIC | c.150G>A p.S50= | Silent (SNP) | VAF 69/133 reads (52%) | catalogued as rs770314510, COSV59414151, COSV59418099; called by muse, mutect2, varscan2
- PTPN21 | c.2397C>T p.S799= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as rs559000618; called by muse, mutect2
- RUFY4 | c.1113G>T p.L371= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs755960868; called by muse, mutect2, varscan2
- RYR3 | c.2673C>T p.F891= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as rs1018585519; called by muse, mutect2, varscan2
- TAB3 | c.1488G>A p.K496= | Silent (SNP) | VAF 58/59 reads (98%) | catalogued as COSV55836654; called by muse, mutect2, varscan2
- TTC12 | c.172A>C p.R58= | Silent (SNP) | VAF 49/292 reads (17%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.21G>C p.S7= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as COSV53074366; called by muse, mutect2, varscan2
- WDR7 | c.1257A>G p.G419= | Silent (SNP) | VAF 83/186 reads (45%) | called by muse, varscan2
- AC114741.1 | n.6C>T | RNA (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2
- ACAT2 | c.634+12A>T | Intron (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2
- ATP8B4 | c.*1140T>C | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- ATXN2L | c.300-838G>A | Intron (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- BCL7A | c.-89A>C | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- BRI3BP | c.*3370G>A | 3'UTR (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- C4BPA | c.*191T>C | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- CACTIN | c.*156-21C>T | Intron (SNP) | VAF 52/102 reads (51%) | catalogued as rs756238298; called by muse, mutect2, varscan2
- CACTIN | c.*156-22C>A | Intron (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- CCP110 | c.*1301A>C | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- CDR2L | c.*127G>A | 3'UTR (SNP) | VAF 75/150 reads (50%) | called by muse, mutect2, varscan2
- CFLAR | c.524-1942G>A | Intron (SNP) | VAF 54/121 reads (45%) | catalogued as rs1025400752; called by muse, mutect2, varscan2
- CNOT3 | c.2038-30del | Intron (DEL) | VAF 11/26 reads (42%) | catalogued as rs774257009; called by mutect2, pindel, varscan2
- COL12A1 | c.9181+382A>G | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- CPEB4 | c.-85_-81del | 5'UTR (DEL) | VAF 22/42 reads (52%) | called by mutect2, pindel, varscan2
- DEAF1 | c.*130G>A | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- DHCR24 | c.*1816G>A | 3'UTR (SNP) | VAF 33/55 reads (60%) | catalogued as rs1185120553; called by muse, mutect2, varscan2
- DIP2C | c.85+39112C>T | Intron (SNP) | VAF 42/93 reads (45%) | catalogued as rs375788699; called by muse, mutect2, varscan2
- DNAJC5 | c.*1564G>A | 3'UTR (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- ELP4 | chr11:31788992 A>T | 3'Flank (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- ENHO | c.*348A>C | 3'UTR (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- FAM171B | c.*615A>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- FOLH1 | c.118+403G>T | Intron (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.540C>T | RNA (SNP) | VAF 87/89 reads (98%) | called by muse, mutect2, varscan2
- GLS | c.1650+3222A>G | Intron (SNP) | VAF 49/90 reads (54%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1720G>A | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.298-4411T>C | Intron (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- HAS2-AS1 | n.1044A>G | RNA (SNP) | VAF 11/25 reads (44%) | called by mutect2, varscan2
- HNRNPH1 | c.*465T>C | 3'UTR (SNP) | VAF 75/197 reads (38%) | called by muse, mutect2, varscan2
- HPGD | chr4:174522654 T>C | 5'Flank (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- LRIT2 | c.*114C>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.4822+2063T>C | Intron (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- LSM8 | c.31+328G>A | Intron (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- MCC | c.-1C>T | 5'UTR (SNP) | VAF 22/56 reads (39%) | catalogued as rs1561598811; called by muse, mutect2, varscan2
- MCF2 | c.-171T>C | 5'UTR (SNP) | VAF 57/59 reads (97%) | called by muse, mutect2, varscan2
- MTFP1 | c.*475T>A | 3'UTR (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- NEK3 | c.603+18A>G | Intron (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- NR3C2 | c.*569C>T | 3'UTR (SNP) | VAF 28/339 reads (8%) | called by muse, mutect2
- P2RX6 | c.*1963G>A | 3'UTR (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- PDE2A | c.1537+83del | Intron (DEL) | VAF 56/139 reads (40%) | called by mutect2, pindel, varscan2
- PTPRK | chr6:127969453 A>G | 3'Flank (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- RBM39 | c.1414-15dup | Intron (INS) | VAF 10/18 reads (56%) | catalogued as rs756882149, COSV53616782; called by mutect2, varscan2
- RIC8A | c.-675T>G | 5'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- SERPINB7 | c.*494del | 3'UTR (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- SHPRH | c.*1825A>G | 3'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs1382390247; called by muse, mutect2, varscan2
- SLC16A11 | c.-52C>A | 5'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- SMAD4 | c.*5012T>A | 3'UTR (SNP) | VAF 31/53 reads (58%) | called by muse, mutect2, varscan2
- STPG2 | c.*3184A>C | 3'UTR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- SWT1 | c.*604T>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- TBC1D31 | c.77+496T>G | Intron (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- TERF2IP | c.670+118T>C | Intron (SNP) | VAF 80/175 reads (46%) | called by muse, mutect2, varscan2
- TMPRSS4 | c.*2170A>C | 3'UTR (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- WDR86 | c.163+431G>A | Intron (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- ZFHX4 | c.*1871A>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- ZNF75A | c.*344G>T | 3'UTR (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
